Somatic mutation profile of tumor specimen C3N-01857-01 (aliquot CPT0162140007) from CPTAC case C3N-01857, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.6 years (25,423 days).
Specimen C3N-01857-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0a030e4-f4d4-417a-a255-3e58d59c2cb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01857-31 (Blood Derived Normal), aliquot CPT0162170002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a62c944b-c0da-4e2a-9930-585b66393db1

The open-access MAF lists 87 somatic variants for this specimen: 55 protein-altering or splice-affecting, 20 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 20, Intron 5, 3'UTR 3, RNA 3, Frame Shift Del 2, In Frame Del 1, Nonsense Mutation 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- WAS | c.134C>T p.T45M | Missense Mutation (SNP) | VAF 160/360 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs132630273, CM103922, CM951313, COSV64997200; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABHD6 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 99/236 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.439); catalogued as COSV99917008; called by muse, mutect2, varscan2
- ACTL9 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.397); catalogued as COSV61006300; called by muse, mutect2
- ATP1B4 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 86/239 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs992806177, COSV54311395; called by muse, mutect2, varscan2
- BCL11B | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.971); catalogued as rs375841913; called by muse, mutect2, varscan2
- BPI | c.593G>A p.R198Q (on ENST00000262865; = p.R194Q on NM_001725.3) | Missense Mutation (SNP) | VAF 53/260 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.113); catalogued as rs749629986, COSV53404895, COSV53408318; called by muse, mutect2, varscan2
- C6 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 159/398 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs776129858; called by muse, mutect2, varscan2
- CDC42BPA | c.3569A>G p.N1190S (on ENST00000334218 / NM_001366019.2; = p.N1177S on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 133/348 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1282754060; called by muse, mutect2, varscan2
- CTAGE1 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 82/197 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779323685; called by muse, mutect2, varscan2
- DLG3 | c.1795G>A p.D599N | Missense Mutation (SNP) | VAF 111/347 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs747352979; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK7 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 105/256 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.052); catalogued as rs1408421974, COSV52014866; called by muse, mutect2, varscan2
- DPP10 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1197469756, COSV59696895; called by muse, mutect2, varscan2
- ELOA2 | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 152/341 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs572647337, COSV55296268; called by muse, mutect2, varscan2
- EMILIN3 | c.1630A>G p.S544G | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as COSV60036861; called by muse, mutect2, varscan2
- KIF12 | c.1024G>A p.V342M (on ENST00000640217; = p.V204M on NM_138424.1) | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs564811653, COSV65116717; called by muse, mutect2, varscan2
- MS4A1 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 77/230 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs371479947; called by muse, mutect2, varscan2
- MUC16 | c.28850G>A p.R9617K | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.019); catalogued as rs746625906; called by muse, mutect2, varscan2
- NLRC5 | c.5294C>T p.T1765M | Missense Mutation (SNP) | VAF 70/239 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs936423148, COSV99348309; called by muse, mutect2, varscan2
- NLRP11 | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as rs116279591, COSV64086582; called by muse, mutect2, varscan2
- NUDT7 | c.232C>A p.R78S | Missense Mutation (SNP) | VAF 69/149 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0.124); catalogued as COSV51744464; called by muse, mutect2, varscan2
- PCDHA9 | c.1844C>T p.T615M | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); catalogued as rs555417773, COSV65334252; called by muse, mutect2
- PDPR | c.605A>T p.N202I | Missense Mutation (SNP) | VAF 121/876 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.094); catalogued as COSV55348728; called by muse, mutect2, varscan2
- PIK3R5 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1453070231, COSV52658686, COSV52658933; called by muse, mutect2, varscan2
- PLXNB3 | c.2533G>A p.G845S | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs782232949; called by muse, mutect2, varscan2
- PRB4 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs374921001, COSV54395119; called by muse, mutect2, varscan2
- PRKX | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 169/385 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.72); catalogued as rs1372259900, COSV99468413; called by muse, mutect2, varscan2
- PTCHD4 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as rs371091755; called by muse, mutect2, varscan2
- RYR1 | c.4444G>A p.V1482I | Missense Mutation (SNP) | VAF 80/306 reads (26%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.832); catalogued as rs747718728; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN9A | c.4942G>A p.G1648S (on ENST00000303354; = p.G1637S on NM_002977.3) | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1231385530; called by muse, mutect2, varscan2
- SLC6A3 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs761418909, COSV54368242; called by muse, mutect2, varscan2
- SRCAP | c.8380C>T p.R2794C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs139190108; ClinVar: uncertain significance; called by muse, varscan2
- SUSD3 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); catalogued as rs940036240; called by muse, mutect2, varscan2
- TERT | c.2422G>A p.V808I | Missense Mutation (SNP) | VAF 97/249 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as rs200119385, COSV57236164; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRPC7 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 89/234 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs779338400; called by muse, mutect2, varscan2
- UTP20 | c.6736C>T p.R2246W | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs753392000, COSV55384710; called by muse, mutect2, varscan2
- WIPF3 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs754655046, COSV54210700; called by muse, mutect2, varscan2
- WNK3 | c.4000C>T p.R1334W | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201834658, COSV63615995; called by muse, mutect2, varscan2
- ZFR2 | c.1808C>T p.T603M | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs199699070; called by muse, mutect2, varscan2
- ZNF518B | c.1359_1362del p.F454Lfs*27 | Frame Shift Del (DEL) | VAF 55/143 reads (38%) | catalogued as rs761062140; called by mutect2, pindel, varscan2
- ADAMTS15 | c.218A>C p.Q73P | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- BOD1L1 | c.4720C>A p.L1574I | Missense Mutation (SNP) | VAF 87/188 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CLUH | c.3233del p.L1078Rfs*5 (on ENST00000435359; = p.L1117Rfs*5 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 26/93 reads (28%) | called by mutect2, pindel, varscan2
- DACH1 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DENND1C | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- EPB41 | c.2490T>G p.H830Q (on ENST00000343067 / NM_001166005.2; = p.H554Q on NM_004437.4) | Missense Mutation (SNP) | VAF 113/290 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- FMNL3 | c.2990_2992del p.I997del | In Frame Del (DEL) | VAF 52/130 reads (40%) | called by pindel, varscan2
- KIAA0100 | c.5063G>A p.W1688* | Nonsense Mutation (SNP) | VAF 37/100 reads (37%) | called by muse, mutect2, varscan2
- MED12 | c.5589dup p.P1864Tfs*31 | Frame Shift Ins (INS) | VAF 119/326 reads (37%) | called by mutect2, pindel, varscan2
- MOGS | c.779A>G p.Y260C | Missense Mutation (SNP) | VAF 91/246 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MROH2A | c.1799T>C p.L600P | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYDGF | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOL8 | c.3113C>A p.A1038D | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NSMAF | c.2429A>G p.D810G | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- TRAF7 | c.751C>A p.L251I | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- TSHZ2 | c.634G>T p.A212S | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACTL9 | c.996G>A p.A332= | Silent (SNP) | VAF 62/178 reads (35%) | catalogued as rs1369590050, COSV61006527; called by muse, mutect2, varscan2
- ADGRG5 | c.189C>A p.G63= | Silent (SNP) | VAF 116/294 reads (39%) | called by muse, varscan2
- CACNA1I | c.1440C>T p.H480= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as rs1018304546; called by muse, mutect2, varscan2
- CEP295 | c.5817A>G p.A1939= | Silent (SNP) | VAF 67/191 reads (35%) | catalogued as rs572754543; called by muse, mutect2, varscan2
- CFC1 | c.219G>A p.P73= | Silent (SNP) | VAF 105/558 reads (19%) | catalogued as rs556034284, COSV52090353; called by muse, mutect2, varscan2
- EPHB2 | c.3159C>T p.C1053= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs761622826; called by muse, mutect2
- FCN2 | c.414C>T p.D138= | Silent (SNP) | VAF 30/177 reads (17%) | catalogued as rs768992885, COSV99391214; called by muse, mutect2, varscan2
- FER1L6 | c.3162C>T p.N1054= | Silent (SNP) | VAF 56/145 reads (39%) | catalogued as rs770073727, COSV67547899; called by muse, mutect2, varscan2
- GPX3 | c.189C>T p.Y63= | Silent (SNP) | VAF 43/99 reads (43%) | catalogued as rs766813820, COSV100161051; called by muse, mutect2, varscan2
- KCNK13 | c.744C>T p.N248= | Silent (SNP) | VAF 107/255 reads (42%) | catalogued as rs574638305, COSV56411938; called by muse, mutect2, varscan2
- KIF26B | c.1242G>A p.P414= | Silent (SNP) | VAF 104/276 reads (38%) | catalogued as rs567652329, COSV63639230; called by muse, mutect2, varscan2
- MAPK9 | c.1173A>G p.S391= | Silent (SNP) | VAF 50/121 reads (41%) | called by muse, mutect2, varscan2
- MUC12 | c.6216C>T p.G2072= (on ENST00000379442; = p.G1929= on NM_001164462.1) | Silent (SNP) | VAF 84/2206 reads (4%) | catalogued as rs963485025; called by muse, mutect2
- MUC16 | c.36465C>T p.L12155= | Silent (SNP) | VAF 76/287 reads (26%) | catalogued as rs766440745, COSV67479426; called by muse, mutect2, varscan2
- OR4K1 | c.456C>T p.G152= | Silent (SNP) | VAF 77/485 reads (16%) | catalogued as rs762768302, COSV53459799; called by muse, mutect2, varscan2
- PCDHA3 | c.276C>T p.R92= | Silent (SNP) | VAF 179/435 reads (41%) | catalogued as rs1466324759; called by muse, mutect2, varscan2
- S1PR4 | c.306C>T p.N102= | Silent (SNP) | VAF 83/298 reads (28%) | catalogued as rs376348566; called by muse, mutect2, varscan2
- SHROOM4 | c.4132C>T p.L1378= | Silent (SNP) | VAF 120/272 reads (44%) | called by muse, mutect2, varscan2
- TRPC7 | c.462C>T p.Y154= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as rs1233289175, COSV61459456; called by muse, mutect2, varscan2
- ZSWIM9 | c.162G>A p.A54= | Silent (SNP) | VAF 88/328 reads (27%) | catalogued as rs1326527836; called by muse, mutect2, varscan2
- AC011294.1 | n.419G>A | RNA (SNP) | VAF 44/147 reads (30%) | catalogued as rs545168572; called by muse, mutect2, varscan2
- ASIC1 | c.559-3404C>T | Intron (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- EI24P4 | n.830G>A | RNA (SNP) | VAF 98/288 reads (34%) | catalogued as rs900957715; called by muse, mutect2, varscan2
- EPB41L3 | c.*7-27G>A | Intron (SNP) | VAF 40/112 reads (36%) | called by muse, mutect2, varscan2
- FAM90A27P | n.538C>T | RNA (SNP) | VAF 45/225 reads (20%) | catalogued as rs1407102458; called by muse, mutect2, varscan2
- IL6R | c.949+1408A>G | Intron (SNP) | VAF 28/63 reads (44%) | catalogued as rs1327758909; called by muse, mutect2, varscan2
- KEL | c.*15A>T | 3'UTR (SNP) | VAF 105/368 reads (29%) | called by muse, mutect2, varscan2
- KYAT3 | c.*18_*20del | 3'UTR (DEL) | VAF 36/93 reads (39%) | catalogued as rs764246820; called by mutect2, pindel, varscan2
- LRRC37A4P | n.5180+9G>A | Intron (SNP) | VAF 125/143 reads (87%) | called by muse, mutect2, varscan2
- RNF212 | c.172-2901C>T | Intron (SNP) | VAF 115/281 reads (41%) | catalogued as rs1391072955; called by muse, mutect2, varscan2
- SATL1 | c.-315G>T | 5'UTR (SNP) | VAF 138/395 reads (35%) | called by muse, mutect2, varscan2
- ZNF99 | c.*3184C>A | 3'UTR (SNP) | VAF 35/121 reads (29%) | called by muse, mutect2, varscan2
